Surgical pathology report (de-identified scan), TCGA case TCGA-MX-A666, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MSKCC, specimen TCGA-MX-A666-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Adenocarcinoma, NOS 8/14/13
Site: Incisura stomach C16.9
JW 5/10/13

* Addendum *

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastrointestinal
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] (Age: [REDACTED] M Date of Receipt:
Physician: [REDACTED], M.D. Date of Report:
CC: [REDACTED] M.D.
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Gastric carcinoma, mass- lesser curve. Rule out carcinoma.

Specimens Submitted:

1: Mass, incisura

DIAGNOSIS:

1. Stomach, incisura; biopsy:
- Infiltrating adenocarcinoma, moderately differentiated, see note

Note: Results of analysis for Her-2 immunorexpression will be separately reported in an addendum.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

M.D.

*** Report Electronically Signed Out ***

Gross Description:

H.T.

1). The specimen is received in formalin, labeled "mass, incisura ", and consists of three pieces of tan soft tissue ranging from 0.2 to 0.4 cm. The specimen is entirely submitted one cassette(s).

Summary of Sections:

Part 1: Mass, incisura

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED], M.D.

Service: Gastrointestinal

Date of Report:

Page 2 of 2

Block 1 Sect. Site {not entered} PCs

3

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

Date Reported:

Addendum Diagnosis

1. Stomach, incisura, biopsy:

-Performed immunohistochemical stain reveals that the carcinoma cells are negative for Her-2 (0).

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

*** Report Electronically Signed Out ***

Signed out by

M.D.

** End of Report **

MDA Discrepancy		✓
Prior Multisite History		✓

Source: NCI Genomic Data Commons file 69888c7a-efb4-479c-a744-29e29ee50b65 (TCGA-MX-A666.1128EE09-2BC3-41C2-857C-E26144AB4C11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).